Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8679, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8679-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]		
[REDACTED] Case ID	[REDACTED] ID	Excision date
[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details

[page 3 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Subtotal resection of stomach Tumor site: Fundus Tumor size: 4 x 4 x 3 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Muscularis propria Lymph nodes: 0/11 positive for metastasis (Regional 0/11) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file f67b8c9e-b979-429b-a25c-1442e6409b43 (TCGA-BR-8679.2962A88D-2B4B-4F2D-8733-3001368D080C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).